Somatic mutation profile of tumor specimen MMRF_1453_1_BM_CD138pos (aliquot MMRF_1453_1_BM_CD138pos_T2_KAS5U_L02371) from MMRF case MMRF_1453, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.7 years (18,883 days).
Specimen MMRF_1453_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65c035c6-a2ef-43c9-84d2-d78b41b7873d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1453_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1453_1_PB_Whole_C3_KAS5U_L02379; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4a8bd71-4076-4be3-ae31-796817a9ed89

The open-access MAF lists 231 somatic variants for this specimen: 98 protein-altering or splice-affecting, 32 silent, 101 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, 3'UTR 52, Intron 33, Silent 32, 5'Flank 7, 3'Flank 4, Nonsense Mutation 3, 5'UTR 3, Splice Site 3, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD17 | c.6338G>T p.G2113V | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.04); catalogued as COSV100429852; called by muse, mutect2, varscan2
- ANO3 | c.2812G>A p.V938I | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs774929522, COSV56797580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GAT2 | c.702G>C p.W234C | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1318186542; called by mutect2, varscan2
- BRCA2 | c.8333T>C p.I2778T | Missense Mutation (SNP) | VAF 93/95 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV66451694; called by muse, mutect2, varscan2
- C2orf80 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as rs772328176, COSV58017593; called by muse, mutect2
- CFAP65 | c.3679C>T p.L1227F | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1420015351; called by muse, mutect2, varscan2
- CIRBP | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV100309833; called by muse, mutect2, varscan2
- DCAF12L2 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63582337; called by muse, mutect2, varscan2
- EPHB6 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs1181592235; called by muse, mutect2, varscan2
- ERG | c.1231C>A p.P411T (on ENST00000398919 / NM_001243428.1; = p.P387T on NM_004449.4) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55739966; called by muse, mutect2, varscan2
- FSTL5 | c.1592C>A p.S531Y | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs763754090, COSV60179554; called by muse, mutect2, varscan2
- HEXA | c.1032C>G p.F344L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV51506605; called by muse, mutect2, varscan2
- HS3ST2 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs747167390, COSV54462494; called by muse, mutect2, varscan2
- MFHAS1 | c.197A>G p.E66G | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV52279505; called by muse, mutect2, varscan2
- MMRN1 | c.3131G>T p.S1044I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV53340054; called by muse, mutect2, varscan2
- MTBP | c.1486G>T p.V496F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV59965805; called by muse, mutect2, varscan2
- MYH13 | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV99353393; called by muse, mutect2, varscan2
- NOL8 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150343533; called by muse, mutect2
- NRXN2 | c.2432C>G p.T811R | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99632317; called by muse, mutect2, varscan2
- OR5M1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV73202035; called by muse, mutect2, varscan2
- OTUD3 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 9/105 reads (9%) | catalogued as COSV64296123; called by muse, mutect2
- PANK1 | c.1076A>T p.H359L (on ENST00000307534 / NM_148977.2; = p.H134L on NM_138316.4) | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV56811053; called by muse, mutect2, varscan2
- PCDH18 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 46/460 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV61267388; called by muse, mutect2
- PGBD5 | c.311A>G p.Y104C (on ENST00000525115; = p.Y173C on NM_001258311.2) | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV58412467; called by muse, mutect2
- PLEC | c.10856G>A p.R3619H (on ENST00000322810 / NM_201380.4; = p.R3509H on NM_000445.5) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs548876454, COSV59603009; ClinVar: uncertain significance; called by muse, mutect2
- PTEN | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.174); catalogued as CX110228; called by muse, mutect2, varscan2
- RIT1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1056960726, COSV64171678; called by muse, mutect2
- RNF128 | c.347G>C p.W116S | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375830146, COSV55251295, COSV99718020; called by muse, mutect2, varscan2
- SMO | c.1018C>A p.H340N | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs762297325; called by muse, mutect2, varscan2
- TAC1 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as COSV59988094; called by muse, mutect2, varscan2
- TRIO | c.6676G>A p.E2226K | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs984804041; called by muse, mutect2, varscan2
- TTLL8 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.007); catalogued as rs1431135894; called by muse, mutect2, varscan2
- USH2A | c.5459T>C p.M1820T | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs201643378; called by muse, mutect2, varscan2
- VNN1 | c.566A>T p.N189I | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs746346357; called by muse, mutect2
- ZCCHC3 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1184910751, COSV66643388; called by muse, mutect2, varscan2
- ZSCAN1 | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1399001562, COSV56603728; called by muse, mutect2, varscan2
- AC004593.2 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ALKBH8 | c.58A>T p.R20W | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANPEP | c.1212G>A p.W404* | Nonsense Mutation (SNP) | VAF 58/103 reads (56%) | called by muse, mutect2, varscan2
- ARFGAP3 | c.659A>T p.Q220L | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.164); called by muse, mutect2
- BAZ2B | c.1666T>G p.S556A | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BCLAF1 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BDKRB1 | c.831G>C p.Q277H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CALCOCO1 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CALCRL | c.281_295+1del p.X94_splice | Splice Site (DEL) | VAF 7/84 reads (8%) | called by mutect2, pindel
- CCDC40 | c.2051C>A p.T684N | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.308); called by mutect2, varscan2
- CDH26 | c.1324G>T p.V442F | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CDHR5 | c.1483G>A p.G495S (on ENST00000358353 / NM_001171968.2; = p.G501S on NM_021924.5) | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- CIT | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CLRN2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COBL | c.2264C>A p.S755Y | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- COX18 | c.923C>G p.P308R | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- DHX9 | c.1141-1G>A p.X381_splice | Splice Site (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- DMBX1 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EBF4 | c.1738G>T p.D580Y (on ENST00000609451; = p.D576Y on NM_001110514.1) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ELMOD3 | c.418T>C p.F140L | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- EMSY | c.706A>G p.S236G | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.152); called by muse, mutect2
- EVC2 | c.2175G>T p.Q725H | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.647); called by mutect2, varscan2
- FBN3 | c.4045T>A p.C1349S | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FNDC1 | c.2894C>A p.P965H | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- GPR85 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- GRIN3B | c.2140C>T p.H714Y | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HNRNPLL | c.929A>G p.D310G | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- HTR2C | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ICAM5 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.396); called by muse, mutect2
- IGKV2D-26 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ITPR2 | c.376A>T p.I126L | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- JMJD6 | c.78G>C p.W26C | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- KCNN2 | c.33G>T p.M11I (on ENST00000264773; = p.M223I on NM_021614.4) | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.071); called by muse, varscan2
- KDM3B | c.4206G>C p.W1402C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- KLHDC7A | c.1070C>A p.T357N | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.139); called by muse, mutect2
- LEKR1 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LRRC8D | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRN2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.062); called by muse, mutect2
- NCKAP1 | c.1613A>G p.D538G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- NDUFB1 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFKBIA | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- NPR1 | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PAPPA | c.2555G>A p.G852D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRSS35 | c.405C>G p.D135E | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRS | c.3520G>T p.G1174C | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PUSL1 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- RANBP17 | c.471G>T p.L157F | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SELENOH | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SFTPB | c.544C>G p.P182A | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SH3PXD2B | c.1135T>C p.F379L | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLC25A30 | c.396T>A p.I132= | Splice Region (SNP) | VAF 52/142 reads (37%) | called by muse, mutect2, varscan2
- SLC25A48 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLCO6A1 | c.635A>T p.K212M | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SORCS3 | c.2755C>G p.L919V | Missense Mutation (SNP) | VAF 81/153 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TBC1D32 | c.3752A>C p.N1251T | Missense Mutation (SNP) | VAF 13/452 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- TRPC6 | c.230G>T p.R77I | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TTLL8 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTYH2 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TXNRD2 | c.1183-1G>A p.X395_splice | Splice Site (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- UBA52 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- VANGL1 | c.902G>C p.R301P | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF555 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2
- AGR3 | c.18T>A p.A6= | Silent (SNP) | VAF 10/227 reads (4%) | called by muse, mutect2
- BACH2 | c.2376T>C p.S792= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- BAHCC1 | c.5658G>A p.E1886= | Silent (SNP) | VAF 28/150 reads (19%) | called by muse, mutect2, varscan2
- C11orf94 | c.294A>G p.L98= | Silent (SNP) | VAF 77/184 reads (42%) | catalogued as rs755377155; called by muse, mutect2, varscan2
- C2orf81 | c.1563G>A p.P521= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs1473208486; called by muse, mutect2, varscan2
- CAMKV | c.540C>T p.P180= | Silent (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.1578G>C p.R526= | Silent (SNP) | VAF 16/215 reads (7%) | catalogued as rs1241752306; called by muse, mutect2
- DISP1 | c.3969G>A p.E1323= | Silent (SNP) | VAF 89/329 reads (27%) | called by muse, mutect2, varscan2
- FBXL16 | c.849G>T p.T283= | Silent (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- FIGN | c.1605G>A p.L535= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV100292599; called by muse, mutect2
- GDF10 | c.948G>A p.Q316= | Silent (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- HMCN1 | c.14328G>T p.G4776= | Silent (SNP) | VAF 68/115 reads (59%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.51C>T p.S17= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs376572967; called by muse, varscan2
- IGLV3-1 | c.84A>T p.S28= | Silent (SNP) | VAF 53/90 reads (59%) | catalogued as rs535826903; called by muse, varscan2
- KCNT1 | c.2796G>A p.E932= (on ENST00000488444; = p.E951= on NM_020822.3) | Silent (SNP) | VAF 93/152 reads (61%) | called by muse, mutect2, varscan2
- LAMA1 | c.4608G>T p.G1536= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- LCA5 | c.1977C>T p.L659= | Silent (SNP) | VAF 43/157 reads (27%) | catalogued as rs754960719; called by muse, mutect2, varscan2
- MAP3K4 | c.3225T>C p.N1075= | Silent (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- MARF1 | c.1299C>G p.L433= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- MFAP3L | c.315C>T p.H105= | Silent (SNP) | VAF 14/171 reads (8%) | catalogued as rs769034321, COSV64372269; called by muse, mutect2
- MICAL3 | c.3108C>A p.I1036= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- OGG1 | c.630C>A p.A210= | Silent (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- OOEP | c.228G>T p.T76= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100949790; called by muse, mutect2
- PCNX2 | c.1617C>T p.V539= | Silent (SNP) | VAF 62/428 reads (14%) | catalogued as rs1272152071; called by muse, mutect2, varscan2
- PGR | c.1398G>A p.E466= | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- RORA | c.663C>T p.F221= (on ENST00000335670 / NM_134261.3; = p.F246= on NM_002943.3) | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as rs943309616, COSV99832722; called by muse, mutect2
- SLCO1C1 | c.1236A>T p.I412= | Silent (SNP) | VAF 12/133 reads (9%) | called by muse, mutect2
- SPEG | c.9135G>A p.R3045= | Silent (SNP) | VAF 17/112 reads (15%) | called by muse, mutect2, varscan2
- STAP2 | c.930C>T p.Y310= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs757085436, COSV55699045; called by muse, mutect2, varscan2
- SYT11 | c.438C>A p.T146= | Silent (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- TNC | c.1011A>C p.T337= | Silent (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- UNC13A | c.2499G>A p.V833= | Silent (SNP) | VAF 71/178 reads (40%) | called by muse, mutect2, varscan2
- ABCC5 | c.*622G>A | 3'UTR (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- AC090616.2 | n.362_365del | RNA (DEL) | VAF 58/138 reads (42%) | called by mutect2, varscan2
- AC243547.3 | c.-30+260C>A | Intron (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- ACTR1B | c.*660C>T | 3'UTR (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- ADGRA3 | c.1809+90G>A | Intron (SNP) | VAF 16/86 reads (19%) | catalogued as COSV99292993, COSV99293761; called by muse, mutect2, varscan2
- ASIC5 | c.*71G>C | 3'UTR (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021260 C>T | 5'Flank (SNP) | VAF 47/52 reads (90%) | catalogued as rs541525964, COSV55846296; called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>T | 5'Flank (SNP) | VAF 50/53 reads (94%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- BCLAF1 | c.*452A>G | 3'UTR (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- CAPZB | c.654+30G>A | Intron (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- CCN2 | c.*426C>T | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- CDH6 | c.*134T>C | 3'UTR (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- CDH6 | c.*135C>A | 3'UTR (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99418817; called by muse, mutect2, varscan2
- CDK2AP2 | chr11:67508317 G>A | 5'Flank (SNP) | VAF 48/83 reads (58%) | called by muse, mutect2, varscan2
- CISD1 | c.*930C>G | 3'UTR (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- CLEC4A | c.299-1575G>A | Intron (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- CLPTM1 | c.1038+121C>T | Intron (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- COBLL1 | c.*358A>G | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- COG4 | c.1002+198C>T | Intron (SNP) | VAF 10/11 reads (91%) | called by muse, mutect2, varscan2
- COQ10B | c.*426C>A | 3'UTR (SNP) | VAF 22/37 reads (59%) | called by muse, mutect2, varscan2
- CPED1 | c.540+3866G>A | Intron (SNP) | VAF 4/21 reads (19%) | catalogued as rs1294987267; called by muse, mutect2, varscan2
- CR1 | c.-14T>C | 5'UTR (SNP) | VAF 146/235 reads (62%) | called by muse, mutect2, varscan2
- CTSL | c.126+109G>C | Intron (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- DIABLO | c.97-39C>T | Intron (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- EGFR | c.*3026G>A | 3'UTR (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- EPC2 | c.313+1632G>C | Intron (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2
- EPPIN | c.*484C>G | 3'UTR (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- ESRP1 | chr8:94639285 G>T | 5'Flank (SNP) | VAF 7/181 reads (4%) | called by muse, mutect2
- EZR | c.12+13G>A | Intron (SNP) | VAF 93/150 reads (62%) | called by muse, mutect2, varscan2
- FAM160A1 | c.*392G>A | 3'UTR (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- GALNT17 | c.*797T>A | 3'UTR (SNP) | VAF 30/119 reads (25%) | catalogued as rs988675110; called by muse, mutect2, varscan2
- GLMN | c.*78T>G | 3'UTR (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- GREM2 | c.*1688A>C | 3'UTR (SNP) | VAF 25/258 reads (10%) | called by muse, mutect2
- HEATR1 | c.3459+57G>A | Intron (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- HOXD13 | c.*1007C>A | 3'UTR (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- HTR1F | c.*45G>A | 3'UTR (SNP) | VAF 36/192 reads (19%) | called by muse, mutect2, varscan2
- IFI44L | c.*784A>G | 3'UTR (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2267-4410G>A | Intron (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- LILRB5 | c.1474+137A>G | Intron (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- LY6K | c.218-266C>A | Intron (SNP) | VAF 64/315 reads (20%) | catalogued as rs1164361658; called by muse, mutect2, varscan2
- MIB1 | c.*4209G>T | 3'UTR (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851309 C>A | 5'Flank (SNP) | VAF 48/57 reads (84%) | catalogued as rs745346285; called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46109722 T>A | 5'Flank (SNP) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- MS4A3 | c.156+213G>A | Intron (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- MYCBP2 | c.8026+2949C>G | Intron (SNP) | VAF 6/39 reads (15%) | catalogued as rs1386051996; called by muse, mutect2, varscan2
- MYT1L | c.*430G>A | 3'UTR (SNP) | VAF 43/74 reads (58%) | called by muse, mutect2, varscan2
- NCR3LG1 | c.*1814C>T | 3'UTR (SNP) | VAF 18/131 reads (14%) | called by muse, mutect2, varscan2
- NEBL | c.684+352del | Intron (DEL) | VAF 37/64 reads (58%) | called by mutect2, varscan2*
- NEBL | c.684+350del | Intron (DEL) | VAF 37/65 reads (57%) | called by mutect2, varscan2*
- NNMT | c.*589C>G | 3'UTR (SNP) | VAF 10/84 reads (12%) | catalogued as rs1217310716; called by muse, mutect2, varscan2
- NOX5 | c.*2510C>T | 3'UTR (SNP) | VAF 11/156 reads (7%) | called by muse, mutect2
- NPAT | c.38-11073A>G | Intron (SNP) | VAF 12/23 reads (52%) | catalogued as COSV53716727; called by muse, mutect2, varscan2
- NUCKS1 | c.*215T>A | 3'UTR (SNP) | VAF 85/271 reads (31%) | called by muse, varscan2
- OXCT1 | c.78+139C>T | Intron (SNP) | VAF 6/27 reads (22%) | catalogued as rs1310027311; called by muse, mutect2, varscan2
- PALMD | c.-111G>A | 5'UTR (SNP) | VAF 48/94 reads (51%) | catalogued as rs1194873952; called by muse, mutect2, varscan2
- PAX2 | c.44-251T>G | Intron (SNP) | VAF 79/376 reads (21%) | called by muse, mutect2, varscan2
- PCDH11X | c.*1708T>G | 3'UTR (SNP) | VAF 152/163 reads (93%) | called by muse, mutect2, varscan2
- PDHX | chr11:34916356 G>T | 5'Flank (SNP) | VAF 10/58 reads (17%) | catalogued as rs767425029; called by muse, mutect2, varscan2
- PEX5L | c.22-1497C>T | Intron (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- PFKFB2 | chr1:207079946 T>G | 3'Flank (SNP) | VAF 7/65 reads (11%) | catalogued as rs920211858; called by muse, mutect2, varscan2
- PIDD1 | c.1302+29G>T | Intron (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- PLCL2 | c.327+47890A>T | Intron (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
- PLXDC1 | c.*1857A>T | 3'UTR (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- POC1A | c.*626T>C | 3'UTR (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2
- PPIC | c.231+82A>G | Intron (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- PPP1R3C | c.*102G>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- PPP1R7 | c.303+138C>A | Intron (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- PPP3R2 | c.*112dup | 3'UTR (INS) | VAF 59/146 reads (40%) | called by mutect2, pindel, varscan2
- PPY | chr17:43938832 G>A | 3'Flank (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- PRRT1 | c.*436G>A | 3'UTR (SNP) | VAF 20/238 reads (8%) | catalogued as rs944506973; called by muse, mutect2
- RAB14 | c.*3011G>T | 3'UTR (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2, varscan2
- RABGAP1L | c.1711-89328G>C | Intron (SNP) | VAF 60/286 reads (21%) | catalogued as COSV52320068; called by muse, mutect2, varscan2
- RBM38 | c.416+6613A>G | Intron (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- RCN1 | c.*1185C>T | 3'UTR (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- RIPPLY2 | c.96-33C>G | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as rs533306313; called by muse, mutect2, varscan2
- RNF152 | c.*3793G>A | 3'UTR (SNP) | VAF 44/206 reads (21%) | called by muse, mutect2, varscan2
- RNGTT | c.*1818_*1819insTT | 3'UTR (INS) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- RRM2B | c.*45A>T | 3'UTR (SNP) | VAF 62/368 reads (17%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*4127G>T | 3'UTR (SNP) | VAF 14/99 reads (14%) | called by mutect2, varscan2
- S1PR3 | c.-147-4321G>A | Intron (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- SAFB2 | c.1195+108G>T | Intron (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- SCML2 | c.*1067G>C | 3'UTR (SNP) | VAF 29/70 reads (41%) | catalogued as COSV99318537; called by muse, mutect2, varscan2
- SHF | c.*590T>A | 3'UTR (SNP) | VAF 66/124 reads (53%) | called by muse, mutect2, varscan2
- SLC2A14 | c.-17C>A | 5'UTR (SNP) | VAF 45/170 reads (26%) | catalogued as rs781654415; called by muse, mutect2, varscan2
- SLC35C2 | c.*88T>G | 3'UTR (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- STAT5B | c.*2129G>T | 3'UTR (SNP) | VAF 39/178 reads (22%) | called by muse, mutect2, varscan2
- SYNGR2 | c.338-56G>A | Intron (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- TET2 | c.*467A>T | 3'UTR (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- TMEM38B | c.*417C>T | 3'UTR (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- TPM3 | chr1:154158726 C>T | 3'Flank (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- TRIM24 | c.*3131T>C | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, varscan2
- TRIM24 | c.*3210T>C | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, varscan2
- UBA5 | c.*1295G>C | 3'UTR (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
- UBXN4 | c.*804G>A | 3'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2
- UGDH | c.*788G>A | 3'UTR (SNP) | VAF 21/185 reads (11%) | called by muse, mutect2, varscan2
- VANGL1 | chr1:115692475 C>A | 3'Flank (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- WNT2B | c.*3754C>T | 3'UTR (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- ZGLP1 | c.*54G>A | 3'UTR (SNP) | VAF 23/117 reads (20%) | called by muse, mutect2, varscan2
- ZMAT4 | c.*836T>A | 3'UTR (SNP) | VAF 10/127 reads (8%) | called by muse, mutect2
- ZNF22 | c.*578C>G | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- ZNF252P | n.667A>C | RNA (SNP) | VAF 29/276 reads (11%) | called by muse, mutect2, varscan2
